Somatic mutation profile of tumor specimen ALCH-B36H-TTP1-A (aliquot ALCH-B36H-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B36H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.2 years (17,227 days).
Specimen ALCH-B36H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1cd442d-4b46-4205-b57e-1976b05a440d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36H-NB1-A (Blood Derived Normal), aliquot ALCH-B36H-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4da5ef1-9354-4593-af47-6e7c681339e9

The open-access MAF lists 77 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, Intron 8, Nonsense Mutation 5, RNA 2, Translation Start Site 1, 5'Flank 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 25/522 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- STK11 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881984, CD050018, CM001792, CM147060, COSV58820833, COSV58828324; ClinVar: pathogenic; called by muse, mutect2
- C9 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778186699; called by muse, mutect2
- DIS3 | c.2356A>G p.I786V | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.19); catalogued as rs758280177; called by muse, mutect2
- MAPT | c.775G>T p.A259S (on ENST00000262410 / NM_001377265.1; = p.A184S on NM_016835.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as rs377597373, COSV52240437; called by muse, mutect2, varscan2
- MYH3 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 34/652 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs202142101; called by muse, mutect2
- OR4K2 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | catalogued as COSV53850334; called by muse, mutect2
- OR8A1 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV52509838; called by muse, mutect2
- PCDHGA10 | c.1795G>C p.D599H | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53958411; called by muse, mutect2
- POM121L12 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.605); catalogued as COSV68692550; called by mutect2, varscan2
- PTPRZ1 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV66437594; called by muse, mutect2
- RP1L1 | c.5269G>A p.D1757N | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV66753577; called by muse, mutect2
- SPDYE6 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 48/1650 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV59505746; called by muse, mutect2
- SRRM2 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV57076459; called by muse, mutect2
- SYNE1 | c.15797C>T p.S5266L (on ENST00000367255 / NM_182961.4; = p.S5195L on NM_033071.3) | Missense Mutation (SNP) | VAF 42/641 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs776756326; called by muse, mutect2
- VCAM1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54121456; called by muse, mutect2
- AGMO | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- ATM | c.8204G>T p.C2735F | Missense Mutation (SNP) | VAF 63/591 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ATRX | c.2003C>A p.T668K | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2
- AZGP1 | c.460T>A p.W154R | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CAMTA1 | c.4873C>T p.Q1625* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- CES3 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNR1 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CTDP1 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- DDX54 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOSC10 | c.2344C>G p.R782G (on ENST00000376936 / NM_001001998.3; = p.R757G on NM_002685.4) | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FGF10 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 17/504 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.111); called by muse, mutect2
- G3BP1 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 24/860 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCND1 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2
- MAMDC4 | c.3362G>A p.G1121E (on ENST00000445819; = p.G1042E on NM_206920.3) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP1B | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 24/406 reads (6%) | called by muse, mutect2
- MROH9 | c.654T>G p.H218Q | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- MYH1 | c.4895A>T p.Q1632L | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- MYRF | c.520C>A p.R174S (on ENST00000278836 / NM_001127392.3; = p.R165S on NM_013279.4) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2
- MYT1L | c.2560T>A p.Y854N | Missense Mutation (SNP) | VAF 38/620 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- OR4K2 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR6B2 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PLPPR4 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLPPR4 | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- RPL28 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); called by muse, mutect2
- RTKN2 | c.1409G>T p.W470L | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- RTN4 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNRK | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SOX3 | c.1010C>A p.A337E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); called by muse, mutect2
- TBX15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/196 reads (5%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- TKTL1 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- YY1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ZNF729 | c.3623C>A p.T1208K | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.049); called by muse, mutect2
- ADAMTS12 | c.3981C>A p.T1327= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- ASPM | c.540T>C p.S180= | Silent (SNP) | VAF 43/280 reads (15%) | called by muse, mutect2, varscan2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2
- CHD7 | c.1080A>G p.G360= | Silent (SNP) | VAF 28/737 reads (4%) | called by muse, mutect2
- DMRTA1 | c.1260A>T p.G420= | Silent (SNP) | VAF 27/456 reads (6%) | called by muse, mutect2
- EOGT | c.672T>C p.D224= | Silent (SNP) | VAF 44/386 reads (11%) | called by muse, mutect2, varscan2
- EXOC3 | c.465G>T p.L155= | Silent (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- HPS3 | c.129G>T p.A43= | Silent (SNP) | VAF 16/477 reads (3%) | called by muse, mutect2
- MYH6 | c.3870C>A p.A1290= | Silent (SNP) | VAF 24/642 reads (4%) | called by muse, mutect2
- OR4A5 | c.51G>A p.Q17= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs1196076783; called by muse, mutect2
- PCDHGB4 | c.663C>A p.P221= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as COSV53942017; called by muse, mutect2
- PMP22 | c.123C>T p.N41= | Silent (SNP) | VAF 54/856 reads (6%) | called by muse, mutect2
- SLC26A4 | c.1230G>T p.T410= | Silent (SNP) | VAF 52/608 reads (9%) | catalogued as rs371756312, COSV99707124; called by muse, mutect2
- SPATA31D1 | c.864C>A p.P288= | Silent (SNP) | VAF 24/492 reads (5%) | catalogued as COSV61200964; called by muse, mutect2
- ZNF347 | c.1458G>A p.K486= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as rs1428671964; called by muse, mutect2
- ZNF738 | c.30T>A p.P10= | Silent (SNP) | VAF 48/531 reads (9%) | called by muse, mutect2
- AC136759.1 | n.711G>T | RNA (SNP) | VAF 20/547 reads (4%) | called by muse, mutect2
- ADAM21P1 | n.1360G>C | RNA (SNP) | VAF 26/622 reads (4%) | called by muse, mutect2
- AL645929.2 | chr6:29889813 G>A | 5'Flank (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- EIPR1 | c.259+19108G>C | Intron (SNP) | VAF 26/406 reads (6%) | catalogued as rs749914873; called by muse, mutect2
- FARP1 | c.171+31115C>T | Intron (SNP) | VAF 18/324 reads (6%) | catalogued as rs1335101099; called by muse, mutect2
- FIG4 | c.1039+34G>C | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- GALNS | c.1003-45G>T | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- KANSL2 | c.431-65A>G | Intron (SNP) | VAF 17/374 reads (5%) | called by muse, mutect2
- PAEP | c.422-17C>T | Intron (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- PRND | chr20:4732619 G>T | 3'Flank (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- RPL24 | c.5+15T>C | Intron (SNP) | VAF 22/550 reads (4%) | called by muse, mutect2
- SHROOM4 | c.*1001T>A | 3'UTR (SNP) | VAF 31/828 reads (4%) | called by muse, mutect2
- SLIT2 | c.179+971G>T | Intron (SNP) | VAF 36/508 reads (7%) | called by muse, mutect2
